Somatic mutation profile of tumor specimen TCGA-EI-7002-01A (aliquot TCGA-EI-7002-01A-11D-1924-10) from TCGA case TCGA-EI-7002, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 58.0 years (21,192 days).
Specimen TCGA-EI-7002-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d161405-6b9e-4650-88aa-92c835df68a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EI-7002-10A (Blood Derived Normal), aliquot TCGA-EI-7002-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e803949-88f6-4962-a5ff-fdb0943f96bb

The open-access MAF lists 167 somatic variants for this specimen: 131 protein-altering or splice-affecting, 36 silent.
By variant classification: Missense Mutation 117, Silent 36, Nonsense Mutation 9, Splice Site 2, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 73/115 reads (63%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 48/108 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD2 | c.1391C>G p.S464* | Nonsense Mutation (SNP) | VAF 22/28 reads (79%) | hotspot (GDC flag); catalogued as COSV50992836, COSV50992894, COSV50993280; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 25/33 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AAGAB | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs868733495, COSV56015891; called by muse, mutect2, varscan2
- ABCA3 | c.3694C>T p.R1232C | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs1386770293, COSV57049403; called by muse, mutect2, varscan2
- ABCC11 | c.1967T>G p.L656R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62323219; called by mutect2, varscan2
- ADAMTS19 | c.1171-2A>C p.X391_splice | Splice Site (SNP) | VAF 86/128 reads (67%) | catalogued as COSV50731857; called by muse, mutect2, varscan2
- ADAMTSL3 | c.766A>G p.S256G | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.97); catalogued as COSV54435854; called by muse, mutect2, varscan2
- AKAP6 | c.3147+1G>T p.X1049_splice | Splice Site (SNP) | VAF 22/26 reads (85%) | catalogued as rs1397020168, COSV55204624; called by muse, mutect2, varscan2
- ANO5 | c.2522A>G p.H841R | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61081933; called by muse, mutect2, varscan2
- APC | c.4476del p.T1493Rfs*14 | Frame Shift Del (DEL) | VAF 23/105 reads (22%) | catalogued as COSV57375363; called by mutect2, pindel, varscan2
- ARL11 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs566163670, COSV56290607; called by muse, mutect2, varscan2
- ARX | c.1093C>A p.L365M | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV66874755; called by muse, mutect2, varscan2
- ATG9A | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV60132112; called by muse, mutect2, varscan2
- ATP2A1 | c.1321A>T p.T441S | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV63919908; called by muse, mutect2, varscan2
- ATP2C1 | c.2351T>C p.I784T | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV60752422; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2227C>T p.R743W | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770052600, CM166144, COSV59472442, COSV59480621; called by muse, mutect2, varscan2
- BPGM | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV61323755; called by muse, mutect2, varscan2
- BVES | c.8A>T p.Y3F | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV58946530; called by muse, mutect2
- CACNA2D3 | c.2300C>T p.P767L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99875170; called by muse, mutect2, varscan2
- CAMK2B | c.1424C>T p.P475L | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs537871427, COSV51657322; called by muse, mutect2, varscan2
- CCBE1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768229052, COSV101232777, COSV67949152; called by muse, mutect2, varscan2
- CCDC170 | c.1853A>C p.N618T | Missense Mutation (SNP) | VAF 74/126 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV53336492; called by muse, mutect2, varscan2
- CCDC171 | c.895T>C p.F299L | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV52633924; called by muse, mutect2, varscan2
- CCSER1 | c.1770G>T p.R590S | Missense Mutation (SNP) | VAF 41/46 reads (89%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV61406054; called by muse, mutect2, varscan2
- CD109 | c.1548G>A p.M516I | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV54645107; called by muse, mutect2, varscan2
- CEP44 | c.429A>T p.E143D | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV56658350; called by muse, mutect2, varscan2
- CER1 | c.767G>C p.G256A | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV101097895; called by muse, mutect2, varscan2
- CERT1 | c.1114G>A p.E372K (on ENST00000405807 / NM_001130105.1; = p.E244K on NM_005713.3) | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54655306; called by muse, mutect2, varscan2
- CMYA5 | c.8678C>T p.A2893V | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV71404057; called by muse, mutect2, varscan2
- CMYA5 | c.11897C>T p.A3966V | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.779); catalogued as COSV69745148; called by muse, mutect2, varscan2
- CNGA2 | c.619G>T p.D207Y | Missense Mutation (SNP) | VAF 22/22 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61703075; called by muse, mutect2, varscan2
- COL11A1 | c.2197G>T p.G733C | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473729252, COSV62172526; called by muse, mutect2, varscan2
- COL12A1 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV59389286; called by muse, mutect2, varscan2
- COL13A1 | c.1505G>A p.R502H (on ENST00000398978 / NM_001130103.2; = p.R445H on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371347973; called by muse, mutect2, varscan2
- CSMD1 | c.1130A>G p.E377G (on ENST00000520002; = p.E376G on NM_033225.6) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as rs745748445, COSV101222381; called by mutect2, varscan2
- CTSL | c.639C>G p.Y213* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as COSV58245636; called by muse, mutect2, varscan2
- CUX2 | c.1414G>A p.G472S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs563847572, COSV55624104; called by muse, mutect2, varscan2
- DAPK3 | c.421A>C p.K141Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100009775; called by mutect2, varscan2
- DENND2D | c.473G>T p.S158I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62958464; called by muse, mutect2, varscan2
- DENND4C | c.5422C>G p.L1808V (on ENST00000434457 / NM_001330640.2; = p.L1759V on NM_017925.7) | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV63008308; called by muse, mutect2, varscan2
- DEPDC7 | c.1195A>T p.N399Y (on ENST00000241051 / NM_001077242.2; = p.N390Y on NM_139160.2) | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV53805646; called by muse, mutect2, varscan2
- DHX9 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV62358163; called by muse, mutect2, varscan2
- DIRAS1 | c.356T>A p.V119E | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60214976; called by muse, mutect2
- DNAH17 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 9/15 reads (60%) | catalogued as rs371400048, COSV67749474; called by muse, mutect2, varscan2
- DSCAML1 | c.5141G>C p.R1714P (on ENST00000321322; = p.R1654P on NM_020693.4) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58381061; called by muse, mutect2, varscan2
- DST | c.15294C>A p.N5098K (on ENST00000361203 / NM_001374722.1; = p.N2686K on NM_015548.5) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV54996898; called by muse, mutect2, varscan2
- DYNC1H1 | c.3676C>T p.R1226W | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1000725714, COSV64134252; called by muse, mutect2, varscan2
- DYNC2I1 | c.1379G>A p.R460K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV68103545; called by muse, mutect2, varscan2
- EMG1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99781199; called by muse, mutect2, varscan2
- EMX2 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV71294378; called by muse, mutect2, varscan2
- ESRRG | c.1057G>T p.V353L | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV63149533; called by muse, mutect2, varscan2
- FAM83D | c.1285G>C p.A429P | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV54156454; called by muse, mutect2, varscan2
- FBF1 | c.3240C>A p.S1080R (on ENST00000586717; = p.S1095R on NM_001319193.1) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.919); catalogued as COSV59863549; called by muse, mutect2, varscan2
- GABBR1 | c.1597C>T p.R533W | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1338326885, COSV63540779; called by muse, mutect2, varscan2
- GCOM1 | c.849A>C p.K283N | Missense Mutation (SNP) | VAF 64/75 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV51087952; called by muse, mutect2, varscan2
- GNB1L | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770713977, COSV100284243, COSV61547626; called by muse, mutect2, varscan2
- GON4L | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV55186365; called by muse, mutect2, varscan2
- GPRIN2 | c.1102C>A p.L368M | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV65401642; called by muse, mutect2
- GRM8 | c.1423C>A p.Q475K | Missense Mutation (SNP) | VAF 25/290 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.771); catalogued as COSV58800811; called by muse, mutect2
- GTF3C2 | c.797G>C p.S266T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.024); catalogued as COSV53124956; called by muse, mutect2, varscan2
- H1-8 | c.792A>T p.K264N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV100140090; called by muse, mutect2
- HCFC2 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV57557897; called by muse, mutect2, varscan2
- HEATR1 | c.1465C>A p.H489N | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63979776; called by muse, mutect2, varscan2
- IGLV3-19 | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as rs759155892; called by muse, mutect2, varscan2
- ILVBL | c.877C>A p.Q293K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54617787; called by muse, mutect2, varscan2
- KDM2B | c.1981G>A p.V661M | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs782589352, COSV65638054; called by muse, mutect2, varscan2
- LCE5A | c.313T>A p.S105T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated, low confidence (0.86); PolyPhen possibly damaging (0.503); catalogued as COSV57499874; called by muse, mutect2, varscan2
- LEMD3 | c.2006T>C p.M669T | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs772706117, COSV57648363; called by muse, mutect2, varscan2
- LVRN | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63495889, COSV63498628; called by muse, mutect2, varscan2
- MC1R | c.788T>A p.L263H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM1314004, COSV59624441; called by muse, mutect2, varscan2
- MCHR1 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV50760305; called by muse, mutect2, varscan2
- MUC5B | c.10058C>A p.P3353Q | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV101500541; called by muse, varscan2
- MYO18B | c.4348C>T p.R1450C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs527443272, COSV59124910; called by muse, mutect2, varscan2
- MYO3A | c.2188G>T p.E730* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV56319310, COSV56336606; called by muse, mutect2, varscan2
- NETO1 | c.875G>T p.C292F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55001404; called by muse, mutect2, varscan2
- NOM1 | c.1362A>T p.K454N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV51978785; called by muse, mutect2, varscan2
- NPEPL1 | c.524C>T p.T175I | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as COSV100622485; called by muse, mutect2
- NR0B2 | c.484A>C p.S162R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV99575045; called by muse, mutect2, varscan2
- NSD1 | c.5122A>T p.S1708C | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61770507; called by muse, mutect2, varscan2
- NTN3 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1445146157, COSV99565120; called by muse, mutect2
- OR2W1 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV65851387; called by muse, mutect2, varscan2
- PCDH17 | c.2353G>A p.V785M | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV64971606, COSV64979331; called by muse, mutect2, varscan2
- PCDHGA2 | c.2057A>T p.D686V | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); catalogued as COSV53896539; called by muse, mutect2, varscan2
- PCYT1B | c.51A>C p.Q17H | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.048); catalogued as COSV64775218; called by muse, mutect2, varscan2
- PITPNB | c.214G>T p.V72L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV58060528; called by muse, mutect2, varscan2
- PLPP7 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs377760705; called by muse, mutect2, varscan2
- POSTN | c.983C>A p.T328K | Missense Mutation (SNP) | VAF 92/185 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.796); catalogued as COSV65711795; called by muse, mutect2, varscan2
- PPFIBP1 | c.143C>A p.A48D | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV57287408; called by muse, mutect2, varscan2
- PRKDC | c.3965C>A p.T1322K | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs747889965, COSV58042277; called by muse, mutect2, varscan2
- PSMB9 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV62753711; called by muse, mutect2, varscan2
- PSPC1 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 57/397 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1277188228, COSV58887731; called by muse, mutect2, varscan2
- PTGES | c.421G>C p.A141P | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61392882; called by muse, mutect2, varscan2
- PTPN4 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 26/121 reads (21%) | catalogued as COSV55297222; called by muse, mutect2, varscan2
- QKI | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.769); catalogued as rs142647102; called by muse, mutect2, varscan2
- QKI | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated, low confidence (0.49); PolyPhen probably damaging (0.972); catalogued as COSV51699879; called by muse, mutect2, varscan2
- RBM12 | c.1873A>G p.R625G | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV58289795; called by muse, mutect2, varscan2
- RIPPLY3 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV61566477; called by muse, mutect2, varscan2
- ROGDI | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs749565672, COSV59020646; called by muse, mutect2, varscan2
- RP1 | c.2669C>T p.T890I | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.383); catalogued as rs1442835872, COSV55109779; called by muse, mutect2, varscan2
- RSPH4A | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV57633648; called by muse, mutect2, varscan2
- RYR2 | c.2717C>T p.P906L | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.202); catalogued as rs397516522, COSV63660567; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.12407T>G p.L4136R | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV66534211, COSV66534777; called by muse, mutect2, varscan2
- SEMA3A | c.2121G>A p.M707I | Missense Mutation (SNP) | VAF 47/212 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.265); catalogued as COSV54861384; called by muse, mutect2, varscan2
- SEMG2 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 38/201 reads (19%) | catalogued as rs546357756, COSV65647159; called by muse, mutect2, varscan2
- SFRP4 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52258098; called by muse, mutect2, varscan2
- SH3GL1 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV53655765; called by muse, mutect2, varscan2
- SHROOM2 | c.4324G>A p.E1442K | Missense Mutation (SNP) | VAF 39/43 reads (91%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV66604460; called by muse, mutect2, varscan2
- SIAH3 | c.727C>G p.Q243E | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.767); catalogued as COSV68551307; called by muse, mutect2
- SIPA1L2 | c.4304C>T p.T1435I | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV53383256; called by muse, mutect2, varscan2
- SLC15A4 | c.899A>G p.K300R | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.534); catalogued as COSV57160285; called by muse, mutect2, varscan2
- SYNE1 | c.4523A>C p.Q1508P (on ENST00000367255 / NM_182961.4; = p.Q1515P on NM_033071.3) | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV54903266; called by muse, mutect2, varscan2
- TAS2R43 | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 79/124 reads (64%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV67851997; called by muse, varscan2
- TBXT | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs934235255, COSV51615843, COSV51618021; called by muse, mutect2, varscan2
- TDRD7 | c.3261G>T p.M1087I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV62428267; called by muse, mutect2, varscan2
- TEX14 | c.851G>A p.S284N (on ENST00000240361 / NM_001201457.2; = p.S278N on NM_031272.5) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.211); catalogued as COSV53611530, COSV53615771; called by muse, mutect2, varscan2
- TPRG1L | c.344A>C p.Q115P | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as COSV100754747; called by muse, mutect2, varscan2
- TRIP4 | c.47G>T p.C16F | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.757); catalogued as COSV56029606; called by muse, mutect2, varscan2
- TXNDC2 | c.268C>A p.P90T (on ENST00000306084 / NM_001098529.2; = p.P23T on NM_032243.6) | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.961); catalogued as COSV60151752; called by muse, mutect2, varscan2
- USP31 | c.1994C>A p.P665H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54849161, COSV99566106; called by muse, mutect2, varscan2
- USP45 | c.384T>G p.Y128* | Nonsense Mutation (SNP) | VAF 16/19 reads (84%) | catalogued as COSV57327875; called by muse, mutect2, varscan2
- ZEB1 | c.1495G>A p.A499T | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs139511659; called by muse, mutect2, varscan2
- ZNF92 | c.295A>T p.I99L (on ENST00000328747 / NM_152626.4; = p.I30L on NM_007139.4) | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV60872996; called by muse, mutect2, varscan2
- CENPF | c.1619_1636del p.L540_N545del | In Frame Del (DEL) | VAF 23/179 reads (13%) | called by mutect2, pindel, varscan2
- ERN2 | c.1686dup p.Q563Sfs*7 | Frame Shift Ins (INS) | VAF 11/25 reads (44%) | called by mutect2, pindel, varscan2
- FRMPD4 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); called by muse, mutect2
- IGHV3-48 | c.245C>A p.S82Y | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.58); called by muse, varscan2
- POLR1E | c.1151G>C p.G384A (on ENST00000377792 / NM_001282766.1; = p.G322A on NM_022490.4) | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2
- SIN3B | c.1739A>G p.E580G | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- USP18 | c.744G>T p.L248F | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); called by mutect2, varscan2
- ADCY9 | c.3339G>A p.T1113= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs113410021, COSV53571382; called by muse, mutect2, varscan2
- ADGRB2 | c.1341C>T p.S447= | Silent (SNP) | VAF 17/19 reads (89%) | catalogued as rs530331422, COSV57070428; called by muse, mutect2, varscan2
- ANKS1A | c.2265G>A p.A755= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs377225487; called by muse, mutect2, varscan2
- BCORL1 | c.1413G>A p.G471= | Silent (SNP) | VAF 31/35 reads (89%) | catalogued as COSV54389330; called by muse, mutect2, varscan2
- CACNA2D3 | c.2301T>C p.P767= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99875173; called by muse, mutect2, varscan2
- CD163L1 | c.1122A>G p.G374= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV58010753; called by muse, mutect2, varscan2
- CDX1 | c.547C>A p.R183= | Silent (SNP) | VAF 27/41 reads (66%) | catalogued as rs140956520, COSV51567579; called by muse, mutect2, varscan2
- CSH1 | c.438C>A p.G146= | Silent (SNP) | VAF 16/222 reads (7%) | catalogued as COSV100298393; called by muse, mutect2
- DLX1 | c.468G>A p.P156= | Silent (SNP) | VAF 27/39 reads (69%) | catalogued as rs766704110, COSV59393940; called by muse, mutect2, varscan2
- DNAH11 | c.5403A>T p.T1801= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as COSV60939124; called by muse, mutect2
- DNAH5 | c.9552C>T p.G3184= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV54203231; called by muse, mutect2, varscan2
- EGR3 | c.306C>T p.I102= | Silent (SNP) | VAF 19/27 reads (70%) | catalogued as COSV57832870; called by muse, mutect2, varscan2
- EPHA3 | c.573C>G p.A191= | Silent (SNP) | VAF 82/190 reads (43%) | catalogued as COSV60693654; called by muse, mutect2, varscan2
- FAM135B | c.2706A>G p.E902= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV99425597; called by muse, mutect2
- FAM13A | c.3030G>A p.E1010= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as rs1180507039, COSV51996411; called by muse, mutect2, varscan2
- FBXW11 | c.810G>C p.L270= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV51605238; called by muse, mutect2, varscan2
- FRMD4A | c.2805C>A p.S935= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV62264095; called by muse, mutect2, varscan2
- GDF2 | c.210T>C p.L70= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs782686648; called by muse, mutect2
- GUCY2F | c.3273T>A p.I1091= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99485316; called by muse, mutect2
- HRNR | c.1725G>A p.E575= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as rs779205456, COSV64253966; called by muse, mutect2, varscan2
- MC1R | c.789C>A p.L263= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV59624444; called by muse, mutect2, varscan2
- MMEL1 | c.2196C>A p.A732= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99984122; called by muse, mutect2, varscan2
- MTNR1B | c.831C>T p.N277= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV57065264; called by muse, mutect2, varscan2
- OR52W1 | c.600C>T p.T200= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV60950410; called by muse, mutect2, varscan2
- PCDHB5 | c.756C>T p.P252= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs781839934, COSV50647229; called by muse, mutect2
- RMI1 | c.1848T>G p.L616= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV100366188, COSV57935218; called by muse, mutect2, varscan2
- SEMA4B | c.504G>C p.L168= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs758335362, COSV60172270, COSV60172672; called by mutect2, varscan2
- SGPP1 | c.615C>T p.P205= | Silent (SNP) | VAF 10/10 reads (100%) | catalogued as COSV55974476; called by muse, mutect2, varscan2
- SLC26A5 | c.1488G>C p.L496= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as COSV59697892; called by muse, mutect2, varscan2
- SLC38A7 | c.507C>T p.S169= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs754650697, COSV54702235; called by muse, mutect2, varscan2
- SLCO1C1 | c.426T>C p.S142= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV56868165; called by muse, mutect2, varscan2
- SNCAIP | c.2532C>T p.L844= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV54401927; called by muse, mutect2, varscan2
- SPON1 | c.1272T>C p.D424= | Silent (SNP) | VAF 43/75 reads (57%) | catalogued as rs1554941250, COSV100116270; called by muse, mutect2, varscan2
- STXBP5L | c.2502A>T p.A834= | Silent (SNP) | VAF 42/95 reads (44%) | catalogued as COSV56499479; called by muse, mutect2, varscan2
- TENM4 | c.7092G>A p.G2364= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV53607686; called by muse, mutect2, varscan2
- ZNF765 | c.723A>G p.K241= | Silent (SNP) | VAF 54/66 reads (82%) | catalogued as COSV67182043; called by muse, mutect2, varscan2
